Somatic mutation profile of tumor specimen 0DEFJU from CCDI case PBBNVX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.4 years (890 days).
Specimen 0DEFJU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f81332ce-e069-48c6-bad3-9d3d9a12cf2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE5NB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acbb1a95-437a-444e-b04e-f117dcdae73c

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1F | c.2445_2450del p.E824_E825del | In Frame Del (DEL) | VAF 80/576 reads (14%) | catalogued as rs375862263; called by mutect2*, varscan2
- ITGAX | c.3374C>T p.A1125V | Missense Mutation (SNP) | VAF 108/448 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as rs771872674, COSV51645483; called by muse, mutect2, varscan2
- LIMK1 | c.354C>T p.I118= | Silent (SNP) | VAF 139/513 reads (27%) | catalogued as rs141521880; called by muse, mutect2, varscan2
